Somatic mutation profile of tumor specimen TCGA-17-Z031-01A (aliquot TCGA-17-Z031-01A-01W-0746-08) from TCGA case TCGA-17-Z031, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z031-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18aded85-5a36-47dd-b6aa-04161318df0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z031-11A (Solid Tissue Normal), aliquot TCGA-17-Z031-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7718619-286f-47ec-9b8c-430fb1a01383

The open-access MAF lists 2,468 somatic variants for this specimen: 1,891 protein-altering or splice-affecting, 515 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,655, Silent 515, Nonsense Mutation 123, Splice Site 44, Frame Shift Del 38, Intron 23, RNA 22, Splice Region 14, Frame Shift Ins 10, 3'UTR 10, Translation Start Site 4, 5'Flank 3.

Variants (750 of 2,468; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 142/470 reads (30%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL2A1 | c.3472G>C p.G1158R | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057518911, CM1513382; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.2605G>A p.G869R | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886189, CM950312, COSV60360372; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ECM1 | c.480G>A p.W160* | Nonsense Mutation (SNP) | VAF 291/403 reads (72%) | catalogued as rs1560265435, CM031961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXG1 | c.765G>T p.W255C | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913678, CM082682; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GATA2 | c.1055G>T p.C352F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIN2A | c.96dup p.A33Rfs*105 | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | catalogued as rs1555491538; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 55/135 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554898067, CM1111457, COSV64291669, COSV64295080, COSV64295612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.783-1del p.X261_splice | Splice Site (DEL) | VAF 34/49 reads (69%) | hotspot (GDC flag); catalogued as CS137625, COSV52668714, COSV52729930, COSV53769335; called by mutect2, pindel, varscan2
- TP53 | c.312G>T p.Q104H | Missense Mutation (SNP) | VAF 126/277 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53017086, COSV53120104; called by muse, mutect2, varscan2
- ABCA12 | c.6393G>T p.P2131= (on ENST00000272895 / NM_173076.3; = p.P1813= on NM_015657.3) | Splice Region (SNP) | VAF 45/108 reads (42%) | catalogued as COSV99788462; called by muse, mutect2, varscan2
- ABCA6 | c.3938-1G>T p.X1313_splice | Splice Site (SNP) | VAF 80/279 reads (29%) | catalogued as COSV99446263; called by muse, mutect2, varscan2
- ABCB4 | c.1651C>A p.P551T | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374746433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC3 | c.2752G>T p.G918C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs767575877; called by muse, varscan2
- ACD | c.1105G>T p.G369C (on ENST00000620338; = p.G280C on NM_022914.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.585); catalogued as COSV54670840; called by muse, mutect2
- ACKR1 | c.886C>G p.H296D | Missense Mutation (SNP) | VAF 167/534 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63674574; called by muse, mutect2, varscan2
- ACVR1C | c.546T>C p.G182= | Splice Region (SNP) | VAF 32/128 reads (25%) | catalogued as rs1372285318; called by muse, mutect2, varscan2
- ADA | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774510141, COSV100866542, COSV65739712; called by muse, mutect2, varscan2
- ADAM22 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs761358402, COSV99715777, COSV99718523; called by muse, mutect2, varscan2
- ADAM30 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101023988, COSV65561329; called by muse, mutect2, varscan2
- ADAMTS16 | c.2227T>G p.S743A | Missense Mutation (SNP) | VAF 40/600 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV56982957, COSV57000682, COSV99943085; called by muse, mutect2
- ADAMTS19 | c.2498G>T p.S833I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV50751630; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2604G>T p.K868N | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs767579001, COSV65893449; called by muse, mutect2, varscan2
- ADCY4 | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100156144, COSV100156926; called by muse, mutect2, varscan2
- ADGRG2 | c.1400C>A p.A467D (on ENST00000379869 / NM_001079858.3; = p.A464D on NM_005756.4) | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV61338014; called by muse, mutect2, varscan2
- ADH6 | c.742A>C p.K248Q | Missense Mutation (SNP) | VAF 110/514 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV52958705; called by muse, mutect2, varscan2
- ADRA2C | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57468271; called by muse, mutect2, varscan2
- AGAP1 | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as rs553582318; called by muse, mutect2, varscan2
- AGO1 | c.491T>C p.M164T | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV64596347; called by muse, mutect2
- AHCTF1 | c.3664A>C p.M1222L (on ENST00000366508; = p.M1196L on NM_015446.5) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs538038542; called by muse, varscan2
- AHNAK | c.12011C>T p.P4004L | Missense Mutation (SNP) | VAF 115/407 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470754863; called by muse, mutect2, varscan2
- AHSP | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as rs1418933500; called by muse, mutect2, varscan2
- AKAP17A | c.1780G>T p.G594W | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100001811, COSV100001910; called by mutect2, varscan2
- AKAP3 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.679); catalogued as rs369931580, COSV99961755; called by muse, mutect2, varscan2
- AKAP4 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 180/186 reads (97%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV62074391; called by muse, mutect2, varscan2
- AL592490.1 | c.353C>A p.S118Y | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.497); catalogued as COSV69427926; called by muse, mutect2, varscan2
- ALDH16A1 | c.1438G>T p.G480W | Missense Mutation (SNP) | VAF 90/101 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99512953; called by muse, mutect2, varscan2
- ALK | c.1319C>G p.S440C | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV66575050; called by muse, mutect2, varscan2
- ALMS1 | c.8057C>T p.P2686L | Missense Mutation (SNP) | VAF 165/412 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1269143077; called by muse, mutect2
- ANGPTL5 | c.1008C>A p.N336K | Missense Mutation (SNP) | VAF 142/455 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs139900371, COSV100527643; called by muse, mutect2, varscan2
- ANKRD30A | c.2833C>A p.Q945K (on ENST00000611781; = p.Q889K on NM_052997.2) | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs980920231; called by muse, varscan2
- ANKS1B | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61357220; called by muse, mutect2, varscan2
- ANKS4B | c.985C>A p.L329M | Missense Mutation (SNP) | VAF 79/91 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV61139100; called by muse, mutect2, varscan2
- APOB | c.12117C>A p.F4039L | Missense Mutation (SNP) | VAF 132/360 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51943949; called by muse, mutect2, varscan2
- ARHGEF26 | c.1168A>G p.I390V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.253); catalogued as rs1325874696; called by muse, mutect2, varscan2
- ARID1A | c.2380G>A p.G794R | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV61376065; called by muse, mutect2, varscan2
- ARPP21 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV51794552, COSV51810314; called by muse, mutect2, varscan2
- ASMTL | c.314A>T p.Q105L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs1248861758; called by muse, mutect2, varscan2
- ASNS | c.1556G>T p.R519L | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs568570377, COSV51552688; called by muse, mutect2, varscan2
- ASTN1 | c.1494C>A p.C498* | Nonsense Mutation (SNP) | VAF 386/1532 reads (25%) | catalogued as COSV99920065; called by muse, varscan2
- ATP10D | c.2635G>T p.A879S | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV56708169; called by muse, varscan2
- ATP7B | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV99665990; called by muse, mutect2, varscan2
- AURKB | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60244818; called by muse, mutect2, varscan2
- B4GALNT2 | c.1655A>C p.K552T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV55925633, COSV55925814; called by muse, varscan2
- BAHD1 | c.2078C>G p.S693W | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69084519; called by muse, mutect2, varscan2
- BARHL2 | c.179C>A p.T60K | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as COSV64981980; called by muse, mutect2, varscan2
- BCOR | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100653596; called by muse, mutect2, varscan2
- BDP1 | c.1261A>G p.M421V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs368234778; called by muse, mutect2, varscan2
- BICDL1 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 166/187 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765235056; called by muse, mutect2, varscan2
- BTBD11 | c.2131G>A p.G711S (on ENST00000280758 / NM_001018072.2; = p.G248S on NM_001017523.2) | Missense Mutation (SNP) | VAF 98/108 reads (91%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55025398; called by muse, mutect2, varscan2
- BTRC | c.1313A>T p.Y438F (on ENST00000370187 / NM_033637.4; = p.Y402F on NM_003939.5) | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV64581349; called by muse, mutect2, varscan2
- C12orf42 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 91/98 reads (93%) | catalogued as COSV59392061; called by muse, mutect2, varscan2
- C1QC | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762500174, COSV65889965; called by muse, mutect2, varscan2
- C1orf158 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 89/296 reads (30%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.676); catalogued as COSV55347995; called by mutect2, varscan2
- CACNA1C | c.1481C>G p.A494G | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.344); catalogued as COSV59697712; called by muse, mutect2
- CACNA1E | c.2641C>G p.P881A | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV62387232; called by muse, mutect2, varscan2
- CADM3 | c.448C>A p.L150I (on ENST00000368125 / NM_001127173.3; = p.L184I on NM_021189.5) | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV63684976; called by muse, mutect2, varscan2
- CALCRL | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.687); catalogued as COSV66474166; called by muse, mutect2, varscan2
- CAPN2 | c.1282A>G p.T428A | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs760805402; called by muse, mutect2, varscan2
- CAPZA3 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 86/422 reads (20%) | catalogued as COSV56853073; called by muse, mutect2, varscan2
- CARMIL1 | c.3898G>T p.V1300F | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.027); catalogued as rs760241107; called by muse, mutect2, varscan2
- CASKIN1 | c.686C>A p.A229E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV58878287; called by muse, mutect2, varscan2
- CASS4 | c.1160G>T p.R387L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.03); catalogued as COSV64387627; called by muse, mutect2, varscan2
- CATIP | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV56824048; called by muse, mutect2, varscan2
- CATSPER3 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs373627784; called by muse, mutect2, varscan2
- CCDC170 | c.2091A>T p.K697N | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99498971; called by muse, mutect2, varscan2
- CCDC39 | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 119/235 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs748151034, COSV99870604; called by muse, mutect2, varscan2
- CCDC66 | c.1342C>T p.L448F (on ENST00000394672 / NM_001353147.1; = p.L414F on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750520218; called by muse, mutect2
- CCDC88C | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.05); catalogued as rs747236360; called by muse, mutect2, varscan2
- CCL20 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.744); catalogued as rs755346614, COSV62591355; called by muse, mutect2, varscan2
- CCN6 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 146/473 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1425211874; called by muse, mutect2, varscan2
- CCNY | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV55189450; called by muse, mutect2, varscan2
- CD163L1 | c.2106A>C p.K702N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV58023938; called by muse, mutect2, varscan2
- CD1B | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 565/914 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV63804161, COSV63804598; called by muse, mutect2, varscan2
- CD300LB | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 225/660 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.86); catalogued as rs752893026, COSV58726179; called by muse, mutect2, varscan2
- CD5L | c.564A>C p.Q188H | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV63822560; called by muse, mutect2
- CDCP1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.089); catalogued as rs554090714; called by muse, mutect2, varscan2
- CDH10 | c.2028G>T p.R676S | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV100050436; called by muse, varscan2
- CDH10 | c.2027G>T p.R676M | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52574595; called by muse, varscan2
- CDH10 | c.1838C>A p.A613D | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100051745; called by muse, varscan2
- CDH12 | c.308C>A p.T103N | Missense Mutation (SNP) | VAF 166/397 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV101202052; called by muse, mutect2, varscan2
- CDH17 | c.648G>T p.M216I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV99217248; called by muse, mutect2, varscan2
- CDH8 | c.890G>T p.R297M | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs768132367; called by muse, mutect2, varscan2
- CEMIP2 | c.2560G>C p.D854H | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV65484448; called by muse, mutect2, varscan2
- CEMIP2 | c.1711G>T p.G571C | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs751260196, COSV65486661; called by muse, mutect2, varscan2
- CEP164 | c.3539G>T p.R1180L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV54040543; called by muse, varscan2
- CFAP161 | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54428664, COSV54428904; called by muse, mutect2, varscan2
- CHID1 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs1441052732; called by muse, mutect2, varscan2
- CHL1 | c.2095C>A p.Q699K (on ENST00000397491 / NM_001253387.1; = p.Q715K on NM_006614.4) | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV56608311; called by muse, mutect2, varscan2
- CHODL | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100167155; called by muse, mutect2, varscan2
- CHRM3 | c.434T>G p.L145R | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55097899; called by muse, mutect2
- CHRNA1 | c.622G>C p.D208H (on ENST00000261007 / NM_001039523.3; = p.D183H on NM_000079.4) | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV53682848; called by muse, mutect2, varscan2
- CHST6 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs373710911; called by muse, mutect2, varscan2
- CLDN16 | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 144/251 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV53229265; called by muse, mutect2, varscan2
- CNOT10 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs752322117, COSV59391121; called by muse, mutect2, varscan2
- CNTFR | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145978650, COSV63634349; called by muse, mutect2, varscan2
- CNTNAP2 | c.1998C>A p.S666R | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.401); catalogued as rs759797092, COSV62209179; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COBL | c.2932C>G p.L978V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.138); catalogued as COSV54353105; called by muse, mutect2, varscan2
- COL11A1 | c.3089G>T p.G1030V | Missense Mutation (SNP) | VAF 135/215 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62196220; called by muse, mutect2, varscan2
- COL14A1 | c.2054C>G p.P685R | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52850490; called by muse, mutect2, varscan2
- COL22A1 | c.3828C>T p.G1276= | Splice Region (SNP) | VAF 22/66 reads (33%) | catalogued as COSV57358723; called by muse, mutect2, varscan2
- COL3A1 | c.923G>T p.R308L | Missense Mutation (SNP) | VAF 100/215 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV58581603; called by muse, mutect2
- COL3A1 | c.2678C>A p.P893Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.675); catalogued as COSV58593361; called by muse, mutect2, varscan2
- COL4A2 | c.3385G>T p.D1129Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64635243; called by muse, mutect2
- COL4A6 | c.3836C>A p.P1279Q | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV100565226; called by muse, mutect2, varscan2
- COL5A2 | c.1546G>T p.G516W | Missense Mutation (SNP) | VAF 186/416 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66410737; called by muse, varscan2
- COL6A3 | c.2428C>G p.Q810E | Missense Mutation (SNP) | VAF 67/313 reads (21%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.751); catalogued as COSV99795826; called by muse, mutect2, varscan2
- CORT | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV57630922; called by muse, mutect2, varscan2
- CPAMD8 | c.3056G>A p.R1019H (on ENST00000651564; = p.R972H on NM_015692.5) | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs547742402; called by muse, mutect2, varscan2
- CPED1 | c.2608C>A p.Q870K | Missense Mutation (SNP) | VAF 133/297 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); catalogued as rs1233354229; called by muse, mutect2, varscan2
- CPLX2 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1350139619; called by muse, mutect2, varscan2
- CRISP1 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 189/294 reads (64%) | SIFT tolerated (0.28); PolyPhen benign (0.096); catalogued as COSV59993016; called by muse, mutect2, varscan2
- CRISPLD1 | c.1123A>G p.I375V | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs754422234; called by muse, mutect2, varscan2
- CSMD1 | c.8287T>A p.F2763I (on ENST00000520002; = p.F2762I on NM_033225.6) | Missense Mutation (SNP) | VAF 102/121 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs889533141; called by muse, mutect2, varscan2
- CSMD3 | c.7726C>T p.P2576S (on ENST00000297405 / NM_001363185.1; = p.P2472S on NM_052900.3) | Missense Mutation (SNP) | VAF 107/207 reads (52%) | SIFT tolerated (0.73); PolyPhen benign (0.403); catalogued as rs369267074, COSV52129343; called by muse, mutect2, varscan2
- CSRNP3 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 116/1110 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV58786604; called by muse, mutect2
- CST9L | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65407707; called by muse, mutect2, varscan2
- CTNNA2 | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 70/172 reads (41%) | catalogued as COSV63547968; called by muse, mutect2, varscan2
- CTSE | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as COSV63061906; called by muse, mutect2, varscan2
- CUL9 | c.2584G>T p.G862W | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52726609; called by muse, mutect2, varscan2
- CXCR5 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373196739; called by muse, mutect2, varscan2
- CYP1A1 | c.1183A>C p.S395R | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV65698215; called by muse, mutect2
- CYP27C1 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV58866137; called by muse, mutect2, varscan2
- CYP4F11 | c.1395C>T p.P465= | Splice Region (SNP) | VAF 68/608 reads (11%) | catalogued as COSV99931060; called by muse, mutect2, varscan2
- DAB2 | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 260/538 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); catalogued as rs1400798798; called by muse, varscan2
- DCC | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV59144264; called by muse, mutect2, varscan2
- DCC | c.1532del p.G511Efs*21 | Frame Shift Del (DEL) | VAF 23/97 reads (24%) | catalogued as COSV59106913; called by mutect2, pindel, varscan2
- DEF8 | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51918915; called by muse, varscan2
- DGKB | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51781158; called by muse, mutect2, varscan2
- DGKK | c.756G>T p.A252= | Splice Region (SNP) | VAF 74/170 reads (44%) | catalogued as COSV101052880, COSV101053039; called by muse, mutect2, varscan2
- DHTKD1 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs200814440; called by muse, mutect2, varscan2
- DISC1 | c.125G>T p.R42M | Missense Mutation (SNP) | VAF 70/95 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1288415026; called by muse, mutect2, varscan2
- DLC1 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.003); catalogued as rs1343321465, COSV99364573; called by muse, mutect2, varscan2
- DLG4 | c.265G>A p.G89S (on ENST00000399506 / NM_001321075.3; = p.G132S on NM_001365.4) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs868786374, COSV57242480; called by muse, mutect2, varscan2
- DMRT2 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 146/426 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as rs142906421, COSV52402232; called by muse, mutect2, varscan2
- DMRT3 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV51905581, COSV99506043; called by muse, varscan2
- DMXL1 | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60710638; called by muse, mutect2, varscan2
- DMXL2 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 44/138 reads (32%) | catalogued as rs746881175, COSV51841117; called by muse, mutect2, varscan2
- DNAH7 | c.3526A>T p.R1176W | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV56766342; called by muse, mutect2, varscan2
- DNAJC1 | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1370982908; called by muse, mutect2, varscan2
- DNM1 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM1414152, COSV100360012; called by muse, mutect2, varscan2
- DOCK10 | c.6060C>A p.S2020R | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.21); catalogued as COSV99287672; called by muse, mutect2, varscan2
- DPYS | c.1529del p.T510Kfs*55 | Frame Shift Del (DEL) | VAF 80/176 reads (45%) | catalogued as COSV60912810; called by mutect2, pindel*, varscan2
- DUSP12 | c.1020A>G p.I340M | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as rs1024406352; called by muse, mutect2, varscan2
- DYNC2H1 | c.3091G>C p.D1031H | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV100519959; called by muse, mutect2, varscan2
- EEPD1 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 137/302 reads (45%) | catalogued as COSV54201864; called by muse, mutect2, varscan2
- EHMT1 | c.942G>T p.E314D | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100604139; called by muse, mutect2, varscan2
- ELAPOR2 | c.1590G>T p.M530I (on ENST00000450689 / NM_001142749.3; = p.M363I on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/282 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99789177; called by muse, mutect2, varscan2
- ELSPBP1 | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60413572; called by muse, mutect2, varscan2
- ENPEP | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 52/87 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); catalogued as COSV54453937; called by muse, mutect2, varscan2
- EPAS1 | c.2001G>T p.L667F | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.129); catalogued as COSV55386976; called by muse, mutect2, varscan2
- EPB41L1 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs747082511; called by muse, mutect2, varscan2
- EPB41L2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.524); catalogued as COSV61353116; called by muse, mutect2
- EPB41L3 | c.2686G>T p.A896S | Missense Mutation (SNP) | VAF 88/106 reads (83%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV59464378; called by muse, mutect2, varscan2
- EPHA7 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65169775; called by muse, mutect2, varscan2
- ERN1 | c.2596G>T p.G866W | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70503778; called by muse, mutect2, varscan2
- ERVFRD-1 | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV65369391; called by muse, mutect2, varscan2
- ESRP1 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100619766; called by muse, mutect2, varscan2
- FAM170A | c.887C>A p.A296E | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs760764849, COSV100089208; called by muse, mutect2, varscan2
- FAM214B | c.1547C>T p.T516I | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs947027684; called by muse, mutect2, varscan2
- FAM3B | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.738); catalogued as COSV63613358; called by muse, mutect2, varscan2
- FAM71B | c.1747C>A p.L583M | Missense Mutation (SNP) | VAF 121/290 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1011737977, COSV57227631; called by muse, mutect2, varscan2
- FAM83F | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 178/194 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100328863; called by muse, mutect2, varscan2
- FAM90A1 | c.1278G>C p.Q426H | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.989); catalogued as COSV56715169; called by muse, mutect2, varscan2
- FANCG | c.968T>C p.I323T | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs752346718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT1 | c.6766G>T p.A2256S | Missense Mutation (SNP) | VAF 112/290 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV71675024; called by muse, mutect2
- FAT3 | c.2884G>C p.D962H | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774871868, COSV53101177, COSV53151158; called by muse, mutect2, varscan2
- FBN2 | c.2557A>T p.I853L | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs148598779; called by muse, mutect2, varscan2
- FBXW12 | c.1098C>A p.F366L | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as COSV56482907; called by muse, mutect2, varscan2
- FCRL1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs1417827031, COSV63826093; called by muse, mutect2, varscan2
- FCRL3 | c.1159T>G p.F387V | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as COSV63842985; called by muse, mutect2, varscan2
- FCRL6 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 140/427 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs760326781; called by muse, mutect2, varscan2
- FGA | c.2257C>A p.L753I | Missense Mutation (SNP) | VAF 111/156 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100120218; called by muse, mutect2, varscan2
- FLG | c.11062C>A p.H3688N | Missense Mutation (SNP) | VAF 81/363 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.407); catalogued as COSV100911972, COSV64240363; called by muse, mutect2, varscan2
- FLG | c.2825A>G p.Q942R | Missense Mutation (SNP) | VAF 131/433 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1307830005; called by muse, mutect2, varscan2
- FLG | c.2293C>A p.H765N | Missense Mutation (SNP) | VAF 131/490 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as rs780343509; called by muse, mutect2, varscan2
- FLG2 | c.6846A>C p.Q2282H | Missense Mutation (SNP) | VAF 136/506 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV101166290; called by muse, varscan2
- FLNC | c.1859A>G p.D620G | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs760105162; called by muse, mutect2, varscan2
- FOXD4L5 | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.043); catalogued as COSV66240626; called by mutect2, varscan2
- FOXP2 | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV63493133; called by muse, mutect2, varscan2
- FRAS1 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV53597820; called by muse, mutect2, varscan2
- FRG2B | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs752309592; called by muse, mutect2
- FRG2B | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV101423508; called by muse, mutect2, varscan2
- FRG2C | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV57316456; called by muse, mutect2
- FTSJ3 | c.2092G>T p.E698* | Nonsense Mutation (SNP) | VAF 84/277 reads (30%) | catalogued as COSV100835090; called by muse, varscan2
- FURIN | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99184618; called by muse, mutect2, varscan2
- GABRB1 | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99780026; called by muse, mutect2, varscan2
- GABRB3 | c.275G>T p.W92L | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54684315; called by muse, mutect2, varscan2
- GABRG1 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747255437, COSV54954704; called by muse, mutect2, varscan2
- GABRQ | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 122/128 reads (95%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1251775846, COSV64783079; called by muse, mutect2, varscan2
- GALNT13 | c.1462A>C p.N488H | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV101223708; called by muse, mutect2
- GALNT3 | c.1658G>T p.R553L | Missense Mutation (SNP) | VAF 89/383 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV101204882; called by muse, mutect2, varscan2
- GAP43 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV59343626; called by muse, mutect2, varscan2
- GATA4 | c.825G>T p.Q275H | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1048095136; called by muse, mutect2, varscan2
- GBE1 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as rs772247658, COSV70103568; called by muse, mutect2, varscan2
- GBP7 | c.168C>A p.N56K | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs946548799; called by muse, mutect2, varscan2
- GCH1 | c.646C>G p.R216G | Missense Mutation (SNP) | VAF 93/404 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960728; called by muse, mutect2, varscan2
- GDF15 | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.422); catalogued as COSV53251760; called by muse, mutect2, varscan2
- GGH | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs902321577; called by muse, mutect2, varscan2
- GIMAP1 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as rs1448707179, COSV56190124; called by muse, mutect2, varscan2
- GJA1 | c.895del p.R299Afs*49 | Frame Shift Del (DEL) | VAF 50/209 reads (24%) | catalogued as COSV56999279; called by mutect2, pindel, varscan2
- GJA8 | c.399C>A p.S133R | Missense Mutation (SNP) | VAF 129/182 reads (71%) | SIFT tolerated (0.6); PolyPhen benign (0.188); catalogued as rs782558352, COSV53789270; called by muse, mutect2, varscan2
- GLRA1 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 97/205 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51015683; called by muse, mutect2, varscan2
- GP2 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 129/145 reads (89%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs759085734; called by muse, mutect2, varscan2
- GPC5 | c.384T>G p.S128R | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1275995522; called by muse, mutect2, varscan2
- GPC5 | c.923G>C p.G308A | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as COSV65583300; called by muse, mutect2, varscan2
- GPRC6A | c.1001C>A p.S334Y | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59953130; called by muse, mutect2, varscan2
- GPRIN1 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV99991650; called by muse, mutect2, varscan2
- GRAMD1B | c.1814G>T p.R605L | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV104399297; called by muse, mutect2, varscan2
- GRID2 | c.1637G>A p.G546E | Missense Mutation (SNP) | VAF 85/134 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200446493; called by muse, mutect2, varscan2
- GRK4 | c.1030C>T p.R344* (on ENST00000398052 / NM_182982.3; = p.R312* on NM_005307.3) | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as rs760891038, COSV61668476; called by muse, mutect2, varscan2
- GRK7 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV99379713; called by muse, mutect2, varscan2
- GRM7 | c.2081C>A p.P694H | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63151177; called by muse, mutect2, varscan2
- H1-7 | c.740A>C p.K247T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as COSV58602942; called by muse, mutect2, varscan2
- H3C1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 22/77 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as rs768998955; called by muse, mutect2, varscan2
- HDAC6 | c.2125del p.R709Afs*8 | Frame Shift Del (DEL) | VAF 42/44 reads (95%) | catalogued as COSV61929390; called by mutect2, varscan2
- HEATR1 | c.5629T>G p.F1877V | Missense Mutation (SNP) | VAF 131/579 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV63982083; called by muse, mutect2, varscan2
- HECW2 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 110/273 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs766154324; called by muse, mutect2, varscan2
- HHLA2 | c.992C>A p.T331K | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.224); catalogued as COSV63317769; called by muse, mutect2, varscan2
- HNRNPR | c.1362del p.R455Efs*45 | Frame Shift Del (DEL) | VAF 58/120 reads (48%) | catalogued as rs1557815231, COSV56421435; called by mutect2, varscan2
- HOXD3 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99980510; called by muse, mutect2, varscan2
- HRNR | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV64258743; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1195G>T p.G399W | Missense Mutation (SNP) | VAF 175/198 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52376464, COSV52380091; called by muse, varscan2
- HSD11B1 | c.89-1G>T p.X30_splice | Splice Site (SNP) | VAF 239/331 reads (72%) | catalogued as COSV54827139; called by muse, mutect2, varscan2
- HVCN1 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1310338299; called by muse, mutect2, varscan2
- IFNG | c.99C>A p.N33K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV57492011; called by muse, mutect2
- IFT74 | c.587+1G>T p.X196_splice | Splice Site (SNP) | VAF 28/107 reads (26%) | catalogued as COSV66259871; called by muse, mutect2, varscan2
- IFT81 | c.1869A>C p.K623N | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs982886307, COSV54362077; called by muse, mutect2, varscan2
- IGF1R | c.2068G>T p.E690* | Nonsense Mutation (SNP) | VAF 32/99 reads (32%) | catalogued as COSV51418121; called by muse, mutect2, varscan2
- IGFBP1 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1156892103; called by muse, mutect2, varscan2
- IGHV3-48 | c.205T>G p.Y69D | Missense Mutation (SNP) | VAF 233/692 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as rs782433324; called by muse, varscan2
- IGKV2-30 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 48/686 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs751182381; called by muse, mutect2
- IKZF1 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58783812; called by muse, mutect2
- IL36B | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV52087449, COSV52088998; called by muse, mutect2, varscan2
- INTS4 | c.1492A>G p.T498A | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs777210322; called by muse, mutect2, varscan2
- INVS | c.121A>G p.K41E | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as rs1564123555; called by muse, mutect2, varscan2
- IQGAP2 | c.1853A>C p.K618T | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.084); catalogued as rs763750761; called by muse, mutect2, varscan2
- IRAK4 | c.1224G>T p.K408N | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as COSV71210523, COSV71210697; called by muse, varscan2
- ITFG1 | c.1192G>T p.V398F | Missense Mutation (SNP) | VAF 55/65 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1395519083; called by muse, mutect2, varscan2
- ITIH2 | c.38T>G p.L13R | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV64434344; called by muse, mutect2, varscan2
- ITIH5 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV53668734, COSV99905350; called by muse, mutect2, varscan2
- KCNH3 | c.2083G>T p.G695C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1429394481; called by muse, mutect2, varscan2
- KCNH8 | c.2120C>A p.P707Q | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV60471286; called by muse, mutect2, varscan2
- KCNJ3 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 107/288 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.038); catalogued as COSV54538132; called by muse, mutect2, varscan2
- KCNK10 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56652356; called by muse, mutect2, varscan2
- KDR | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 76/278 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1258995310, COSV55772148; called by muse, varscan2
- KHDRBS2 | c.979T>C p.S327P | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111625311; called by muse, mutect2, varscan2
- KIAA1614 | c.1807G>T p.V603L | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.167); catalogued as COSV62551236; called by muse, mutect2, varscan2
- KIAA1755 | c.324A>C p.Q108H | Missense Mutation (SNP) | VAF 167/742 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54074645, COSV54075379; called by muse, mutect2, varscan2
- KIF12 | c.1793C>T p.P598L (on ENST00000640217; = p.P460L on NM_138424.1) | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.053); catalogued as rs748631116; called by muse, mutect2, varscan2
- KIF4A | c.3674C>T p.S1225F | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs1454486908, COSV99056454; called by muse, mutect2, varscan2
- KIR2DL1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 493/2407 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as COSV99383523; called by muse, varscan2
- KLHDC1 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 138/285 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV63778979; called by muse, mutect2, varscan2
- KLHL13 | c.99-1G>T p.X33_splice | Splice Site (SNP) | VAF 32/41 reads (78%) | catalogued as COSV53245906; called by muse, mutect2, varscan2
- KLHL40 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.817); catalogued as rs1358735543; called by muse, varscan2
- KLRG1 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444952287; called by muse, mutect2, varscan2
- KMT2C | c.13273G>T p.D4425Y | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51487965, COSV51502540; called by muse, mutect2, varscan2
- KRT39 | c.1157A>C p.K386T | Missense Mutation (SNP) | VAF 104/367 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62916932; called by muse, mutect2, varscan2
- KRT6B | c.611A>C p.K204T | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.101); catalogued as COSV52886230; called by muse, mutect2
- KRT76 | c.1167G>T p.R389S | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1490410281, COSV60120394; called by muse, mutect2, varscan2
- KRTAP10-7 | c.808T>G p.C270G | Missense Mutation (SNP) | VAF 118/296 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV59109244; called by muse, mutect2, varscan2
- KRTAP24-1 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100447493; called by muse, mutect2, varscan2
- LAMA3 | c.5420A>G p.N1807S (on ENST00000313654 / NM_198129.4; = p.N198S on NM_000227.6) | Missense Mutation (SNP) | VAF 153/372 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs982053008, COSV52539417; called by muse, mutect2, varscan2
- LAMB3 | c.3328A>G p.T1110A | Missense Mutation (SNP) | VAF 134/476 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs200585982; called by muse, mutect2, varscan2
- LARP1 | c.2672A>G p.H891R (on ENST00000518297 / NM_033551.3; = p.H814R on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/204 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV60432485; called by muse, mutect2, varscan2
- LCE2A | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 114/320 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV64227127; called by muse, varscan2
- LCT | c.3914T>G p.L1305R | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51548452; called by muse, mutect2, varscan2
- LGI2 | c.656-1G>T p.X219_splice | Splice Site (SNP) | VAF 44/98 reads (45%) | catalogued as COSV101180802, COSV66122813; called by muse, mutect2, varscan2
- LPL | c.374C>A p.A125E | Missense Mutation (SNP) | VAF 95/115 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100255705; called by muse, mutect2, varscan2
- LRBA | c.520A>G p.S174G | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.766); catalogued as rs771952832; called by muse, mutect2, varscan2
- LRP1B | c.11073G>C p.W3691C | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1403000738; called by muse, varscan2
- LRP1B | c.10002G>T p.W3334C | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67210054, COSV67254956; called by muse, mutect2, varscan2
- LRP1B | c.4160C>A p.P1387Q | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67236796; called by muse, mutect2, varscan2
- LRP2 | c.6628G>T p.G2210W | Missense Mutation (SNP) | VAF 185/422 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55578763; called by muse, mutect2, varscan2
- LRP2 | c.4015C>A p.P1339T | Missense Mutation (SNP) | VAF 89/239 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99789394; called by muse, mutect2, varscan2
- LRRC37B | c.2273G>T p.G758V | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100496264; called by muse, mutect2, varscan2
- LRRC4B | c.1804C>A p.Q602K | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.54); catalogued as rs1248775945; called by muse, mutect2, varscan2
- LRRC6 | c.981G>T p.M327I | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV51541510; called by muse, mutect2, varscan2
- LRRC66 | c.1267G>T p.E423* | Nonsense Mutation (SNP) | VAF 298/589 reads (51%) | catalogued as COSV58633879; called by muse, mutect2, varscan2
- LRRK2 | c.7374G>A p.M2458I | Missense Mutation (SNP) | VAF 69/115 reads (60%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as rs765994542; called by muse, mutect2, varscan2
- LRRTM4 | c.1742C>A p.P581Q | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101299072, COSV101299177; called by muse, mutect2, varscan2
- MAGEB6B | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.402); catalogued as rs1317147783; called by muse, mutect2, varscan2
- MAGEC3 | c.1048G>A p.G350R | Missense Mutation (SNP) | VAF 84/94 reads (89%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV53578313, COSV53578613; called by muse, mutect2, varscan2
- MAGEE1 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs781944261, COSV63909097; called by muse, mutect2, varscan2
- MAPT | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.34); catalogued as rs143210139; called by muse, mutect2, varscan2
- MAST3 | c.2382G>T p.E794D | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99445873; called by muse, mutect2, varscan2
- MDGA2 | c.1448C>T p.T483M (on ENST00000399232 / NM_001113498.2; = p.T185M on NM_182830.4) | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759450539, COSV62081726; called by muse, mutect2, varscan2
- MDGA2 | c.893A>G p.K298R | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as COSV62085113; called by muse, mutect2
- MED12L | c.5447T>G p.L1816R | Missense Mutation (SNP) | VAF 115/377 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.438); catalogued as COSV56401304; called by muse, mutect2, varscan2
- MEGF10 | c.1844G>C p.C615S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57257961; called by muse, mutect2, varscan2
- MGAT5B | c.1502G>A p.R501Q (on ENST00000569840 / NM_001199172.2; = p.R499Q on NM_144677.3) | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs367973248; called by muse, mutect2, varscan2
- MMRN1 | c.719G>T p.W240L | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53338114; called by muse, mutect2, varscan2
- MMUT | c.1969G>T p.V657L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.529); catalogued as rs370718165; called by muse, mutect2, varscan2
- MON1B | c.1553G>C p.R518P | Missense Mutation (SNP) | VAF 180/583 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99941765; called by muse, mutect2, varscan2
- MORC3 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201006549, COSV68689317; called by muse, mutect2, varscan2
- MPDZ | c.4427G>T p.S1476I | Missense Mutation (SNP) | VAF 102/309 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV100056355; called by muse, mutect2, varscan2
- MREG | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 77/145 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1181196758, COSV54376112; called by muse, mutect2, varscan2
- MSX1 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV66948012; called by muse, mutect2, varscan2
- MTMR8 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 99/106 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768174114; called by muse, mutect2, varscan2
- MUC17 | c.4091A>G p.N1364S | Missense Mutation (SNP) | VAF 59/345 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60293672; called by muse, mutect2, varscan2
- MUC3A | c.8368G>T p.D2790Y | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.29); catalogued as rs891599276, COSV100114369; called by muse, varscan2
- MUC6 | c.5654C>A p.A1885D | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs778471171; called by muse, varscan2
- MYH2 | c.3005A>C p.K1002T | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); catalogued as rs1324293373; called by muse, mutect2, varscan2
- MYH8 | c.3883G>T p.D1295Y | Missense Mutation (SNP) | VAF 61/69 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV101238277; called by muse, mutect2, varscan2
- MYO1D | c.1868G>T p.R623L | Missense Mutation (SNP) | VAF 109/174 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100554336; called by muse, mutect2, varscan2
- MYO3A | c.3082C>G p.L1028V | Missense Mutation (SNP) | VAF 360/799 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as rs1241059681, COSV56326344; called by muse, mutect2, varscan2
- NALCN | c.4990C>T p.Q1664* | Nonsense Mutation (SNP) | VAF 77/309 reads (25%) | catalogued as rs866476189; called by muse, mutect2, varscan2
- NCAN | c.2587G>T p.V863L | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV53060586; called by muse, mutect2, varscan2
- NCKAP5 | c.4081C>G p.Q1361E | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV58476638; called by muse, mutect2, varscan2
- NDST4 | c.1941-1G>C p.X647_splice | Splice Site (SNP) | VAF 27/33 reads (82%) | catalogued as COSV52127875; called by muse, mutect2, varscan2
- NFATC3 | c.2653C>G p.H885D | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as COSV60473499; called by muse, mutect2, varscan2
- NLGN3 | c.1850G>A p.R617Q (on ENST00000358741 / NM_181303.2; = p.R597Q on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62441528; called by muse, mutect2, varscan2
- NLGN4X | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 115/122 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52020493; called by muse, mutect2, varscan2
- NLRP14 | c.606G>T p.E202D | Missense Mutation (SNP) | VAF 132/162 reads (81%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV100205282; called by muse, mutect2, varscan2
- NMUR2 | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV99676979; called by muse, mutect2, varscan2
- NOX5 | c.2003G>T p.R668L | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV52984303; called by muse, mutect2, varscan2
- NPAS4 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100215272; called by muse, mutect2, varscan2
- NPC1L1 | c.3082G>A p.G1028S | Missense Mutation (SNP) | VAF 19/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs984503930, COSV56928378; called by muse, mutect2
- NTM | c.211C>A p.R71S | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66186301; called by muse, mutect2, varscan2
- NTRK1 | c.1946G>T p.R649L | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62327204; called by muse, mutect2, varscan2
- NTRK2 | c.2238T>G p.I746M (on ENST00000323115 / NM_001369534.1; = p.I762M on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/376 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99457040; called by muse, mutect2, varscan2
- NUP205 | c.4423G>T p.A1475S | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as rs566540964, COSV99606971; called by muse, mutect2, varscan2
- NUP93 | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 60/222 reads (27%) | catalogued as COSV57435421; called by muse, mutect2, varscan2
- NUTM1 | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 120/256 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100182308; called by muse, mutect2, varscan2
- NWD1 | c.2872G>A p.E958K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV60341546; called by mutect2, varscan2
- NXF1 | c.232del p.R78Dfs*59 | Frame Shift Del (DEL) | VAF 155/270 reads (57%) | catalogued as COSV53672092; called by mutect2, pindel, varscan2
- NYAP2 | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56003008, COSV56006040; called by muse, mutect2, varscan2
- OPHN1 | c.1918A>T p.I640F | Missense Mutation (SNP) | VAF 103/218 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs778146150; called by muse, mutect2, varscan2
- OPRPN | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 104/165 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.631); catalogued as rs1452728605; called by muse, mutect2, varscan2
- OR10K2 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 26/309 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV59221104; called by muse, mutect2
- OR14K1 | c.447C>A p.N149K | Missense Mutation (SNP) | VAF 240/334 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV51721698; called by muse, mutect2, varscan2
- OR1A1 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58404831; called by muse, mutect2, varscan2
- OR1N2 | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 126/302 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs749350377; called by muse, mutect2, varscan2
- OR2F1 | c.321G>T p.L107F | Missense Mutation (SNP) | VAF 115/519 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.807); catalogued as COSV67332110; called by muse, mutect2, varscan2
- OR2G2 | c.887G>C p.R296T | Missense Mutation (SNP) | VAF 103/414 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60741187; called by muse, mutect2, varscan2
- OR2G3 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 119/624 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767876542; called by muse, varscan2
- OR2G3 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 413/572 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV100180797; called by muse, mutect2, varscan2
- OR2G6 | c.160A>G p.R54G | Missense Mutation (SNP) | VAF 83/368 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs1419482545, COSV100598388; called by muse, mutect2, varscan2
- OR2M2 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 89/476 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100677127; called by muse, mutect2, varscan2
- OR2M3 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 254/1015 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV71759100; called by muse, mutect2, varscan2
- OR2M3 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 375/558 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1385041505, COSV101513384; called by muse, mutect2, varscan2
- OR2Y1 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs771756066; called by muse, mutect2, varscan2
- OR4C12 | c.837G>T p.M279I | Missense Mutation (SNP) | VAF 98/263 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV58859761; called by muse, mutect2, varscan2
- OR4K5 | c.877del p.D293Ifs*2 | Frame Shift Del (DEL) | VAF 160/759 reads (21%) | catalogued as COSV60005456; called by mutect2, pindel, varscan2
- OR4M1 | c.535T>A p.C179S | Missense Mutation (SNP) | VAF 171/954 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100271240; called by muse, varscan2
- OR52N2 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 292/322 reads (91%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs747653202, COSV57676470; called by muse, mutect2, varscan2
- OR5AP2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 116/393 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as rs750046024; called by muse, mutect2, varscan2
- OR5D13 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 89/308 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV100687016; called by muse, mutect2, varscan2
- OR5D13 | c.700A>C p.S234R | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV62333603, COSV62334315; called by muse, mutect2
- OR5D16 | c.320del p.C107Sfs*4 | Frame Shift Del (DEL) | VAF 292/694 reads (42%) | catalogued as COSV65722043; called by pindel, varscan2
- OR5I1 | c.495del p.F166Lfs*3 | Frame Shift Del (DEL) | VAF 95/206 reads (46%) | catalogued as COSV56886043; called by mutect2, pindel, varscan2
- OR5J2 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV56620174, COSV56620483; called by muse, mutect2, varscan2
- OR5M10 | c.547C>G p.P183A | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs773230017; called by muse, mutect2, varscan2
- OR5T1 | c.577A>G p.M193V | Missense Mutation (SNP) | VAF 305/488 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs758889667; called by muse, mutect2, varscan2
- OR5T3 | c.362C>A p.T121N | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs1163677383, COSV57381018; called by muse, mutect2, varscan2
- OR6C3 | c.103A>C p.S35R | Missense Mutation (SNP) | VAF 110/304 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as COSV65570938; called by muse, varscan2
- OR6C75 | c.280G>T p.G94W | Missense Mutation (SNP) | VAF 71/256 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as COSV58551902; called by muse, mutect2, varscan2
- OR6K3 | c.823T>G p.L275V (on ENST00000368146; = p.L259V on NM_001005327.2) | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.993); catalogued as COSV63745754, COSV63746082; called by muse, mutect2, varscan2
- OR7C1 | c.401T>G p.V134G | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV99934787; called by muse, mutect2, varscan2
- OR8G5 | c.32A>C p.K11T | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV100422739, COSV58379665; called by muse, mutect2
- OR8K3 | c.410C>A p.S137* | Nonsense Mutation (SNP) | VAF 55/214 reads (26%) | catalogued as COSV57130661, COSV57131207; called by muse, mutect2, varscan2
- OVCH2 | c.812A>C p.N271T | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as COSV101491952; called by muse, mutect2, varscan2
- OVCH2 | c.660del p.K221Rfs*38 | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | catalogued as COSV101491904; called by mutect2, pindel, varscan2
- P3H3 | c.1707A>G p.I569M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs893577754; called by muse, mutect2, varscan2
- PAPPA2 | c.5167G>T p.D1723Y | Missense Mutation (SNP) | VAF 245/352 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62794188, COSV62810910; called by muse, varscan2
- PAQR3 | c.348+1G>A p.X116_splice | Splice Site (SNP) | VAF 439/535 reads (82%) | catalogued as rs777479143; called by muse, mutect2, varscan2
- PCDH11X | c.3731G>A p.C1244Y | Missense Mutation (SNP) | VAF 142/361 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs756127091; called by muse, mutect2, varscan2
- PCDH15 | c.351G>T p.Q117H | Missense Mutation (SNP) | VAF 66/69 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100217698; called by muse, mutect2, varscan2
- PCDH17 | c.386C>A p.A129E | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV64980270; called by muse, mutect2, varscan2
- PCDH17 | c.2890G>T p.A964S | Missense Mutation (SNP) | VAF 52/58 reads (90%) | SIFT tolerated (0.28); PolyPhen benign (0.111); catalogued as COSV64972286; called by muse, mutect2, varscan2
- PCDH8 | c.422C>A p.P141Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.786); catalogued as rs866733795, COSV100131455, COSV100131624; called by muse, mutect2, varscan2
- PCDHA1 | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as rs782318680; called by muse, varscan2
- PCDHA11 | c.1780C>G p.R594G | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV100247543; called by muse, mutect2, varscan2
- PCDHA8 | c.1342G>C p.V448L | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV65338208; called by muse, mutect2, varscan2
- PCDHB3 | c.1530C>A p.N510K | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.294); catalogued as COSV50567952; called by muse, mutect2, varscan2
- PCDHGA2 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.378); catalogued as COSV53914168; called by muse, mutect2, varscan2
- PCDHGA6 | c.2168G>T p.R723L | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as COSV99531635; called by muse, mutect2, varscan2
- PCDHGB2 | c.125C>A p.A42D | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.074); catalogued as rs535439542, COSV53898506; called by muse, mutect2, varscan2
- PCDHGB6 | c.209C>A p.A70E | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV53959164; called by muse, mutect2, varscan2
- PDCD11 | c.4012G>C p.G1338R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63934198; called by muse, mutect2
- PDCD1LG2 | c.208C>A p.R70S | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs576049863; called by muse, mutect2, varscan2
- PDCD4 | c.1094A>T p.Y365F | Missense Mutation (SNP) | VAF 86/93 reads (92%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as rs756635108; called by muse, mutect2, varscan2
- PDE4A | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs776798161; called by muse, varscan2
- PDE6B | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as CX148735, COSV55325741; called by mutect2, varscan2
- PDK3 | c.895C>A p.R299S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV64793994, COSV64794050; called by muse, mutect2, varscan2
- PDP2 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.963); catalogued as rs375649017; called by muse, mutect2, varscan2
- PDPK1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as rs751870190, COSV51912305, COSV99069944; called by muse, mutect2, varscan2
- PEG3 | c.2444A>G p.H815R | Missense Mutation (SNP) | VAF 287/305 reads (94%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55647201; called by muse, mutect2, varscan2
- PEX5L | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs377328911; called by muse, mutect2, varscan2
- PFKFB1 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | PolyPhen benign (0.02); catalogued as COSV66628770; called by muse, mutect2, varscan2
- PGBD5 | c.1002G>T p.L334F (on ENST00000525115; = p.L403F on NM_001258311.2) | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs1282874376; called by muse, mutect2, varscan2
- PHF24 | c.256C>A p.R86S | Missense Mutation (SNP) | VAF 197/392 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs781343380, COSV54275816; called by muse, mutect2, varscan2
- PITRM1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs750009391; called by muse, mutect2, varscan2
- PKLR | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474390898; called by muse, mutect2, varscan2
- PLA2R1 | c.3611C>T p.S1204F | Missense Mutation (SNP) | VAF 84/164 reads (51%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.823); catalogued as rs910854860; called by muse, mutect2, varscan2
- PLCB2 | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.538); catalogued as COSV53033420; called by muse, varscan2
- PLCL1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 180/350 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357149217, COSV70821581; called by muse, mutect2, varscan2
- PLCL1 | c.1883C>A p.P628Q | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101407166, COSV70851300; called by muse, mutect2, varscan2
- PLEC | c.12934G>C p.E4312Q (on ENST00000322810 / NM_201380.4; = p.E4202Q on NM_000445.5) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1387526087; called by muse, mutect2, varscan2
- PLEKHA8 | c.1464G>C p.R488S | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs769619854; called by muse, mutect2, varscan2
- PLEKHB1 | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV57049710; called by muse, mutect2, varscan2
- PLXDC2 | c.1172G>C p.R391P | Missense Mutation (SNP) | VAF 74/306 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV65906128, COSV65908709; called by muse, mutect2
- PLXNA1 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | catalogued as COSV52527880; called by muse, mutect2, varscan2
- PLXNA4 | c.2400C>A p.H800Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV58149809; called by muse, mutect2, varscan2
- PNMA8A | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 160/271 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs1283213693; called by muse, mutect2, varscan2
- POGZ | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 80/129 reads (62%) | catalogued as COSV55035037; called by muse, mutect2, varscan2
- POTEM | c.37T>A p.S13T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1381620215; called by mutect2, varscan2
- PPFIA2 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.91); catalogued as COSV61046502; called by muse, mutect2, varscan2
- PPP1R1A | c.186C>T p.S62= | Splice Region (SNP) | VAF 90/335 reads (27%) | catalogued as rs772784390; called by muse, mutect2, varscan2
- PREX1 | c.989G>C p.R330P | Missense Mutation (SNP) | VAF 172/374 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64256441; called by muse, mutect2, varscan2
- PRICKLE3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 81/168 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781815124, COSV66235552; called by muse, mutect2, varscan2
- PRKCQ | c.1600G>T p.A534S | Missense Mutation (SNP) | VAF 123/313 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs1443554970; called by muse, mutect2, varscan2
- PRPS2 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 268/285 reads (94%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.771); catalogued as COSV66126585; called by muse, mutect2, varscan2
- PRRC2A | c.4166G>A p.R1389Q | Missense Mutation (SNP) | VAF 121/337 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779714705, COSV65687909; called by muse, mutect2, varscan2
- PRSS23 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54707788; called by muse, mutect2, varscan2
- PRSS55 | c.1058G>C p.*353Sext*1 | Nonstop Mutation (SNP) | VAF 107/130 reads (82%) | catalogued as rs112308687; called by muse, mutect2, varscan2
- PRSS58 | c.709G>T p.V237L | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs768963947; called by muse, mutect2, varscan2
- PSG2 | c.944C>G p.S315W | Missense Mutation (SNP) | VAF 364/394 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs749542888, COSV61544757; called by muse, varscan2
- PSG3 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 320/1386 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1341716048; called by muse, varscan2
- PSME4 | c.2221G>T p.G741C | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as COSV101122690; called by muse, mutect2, varscan2
- PTEN | c.165-1G>T p.X55_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as CS110220, COSV64291262, COSV64292036, COSV64304032; called by muse, mutect2, varscan2
- PTER | c.698+1G>T p.X233_splice | Splice Site (SNP) | VAF 113/274 reads (41%) | catalogued as COSV54345068; called by muse, mutect2, varscan2
- PTPN14 | c.1529T>G p.L510R | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.049); catalogued as rs1159762653, COSV65285290; called by muse, mutect2
- PTPRN2 | c.1676G>C p.S559T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.565); catalogued as rs1479360422; called by muse, mutect2, varscan2
- PTPRS | c.1738G>A p.V580M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.785); catalogued as rs374725933; called by muse, varscan2
- PYHIN1 | c.1118G>T p.R373L | Missense Mutation (SNP) | VAF 76/127 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV63722274, COSV63723097; called by muse, mutect2, varscan2
- RAB11FIP2 | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.028); catalogued as rs991702109; called by muse, mutect2
- RB1 | c.1049G>T p.S350I | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1368390928, COSV57300027; called by muse, mutect2, varscan2
- RBM47 | c.1166G>A p.R389K | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99921933; called by muse, mutect2, varscan2
- RC3H2 | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV100106588; called by muse, mutect2, varscan2
- RCVRN | c.183C>A p.D61E | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as rs776177327; called by muse, mutect2, varscan2
- REG1A | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 224/624 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV52069806; called by muse, varscan2
- RELCH | c.2642A>T p.Q881L | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.2); PolyPhen benign (0.39); catalogued as COSV56882347; called by muse, mutect2, varscan2
- RFX6 | c.1370A>C p.K457T | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV60584311; called by muse, mutect2, varscan2
- RGS8 | c.416C>A p.S139Y (on ENST00000367556 / NM_001369564.2; = p.S157Y on NM_033345.3) | Missense Mutation (SNP) | VAF 161/262 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51114910; called by muse, mutect2, varscan2
- RGS9 | c.1626C>A p.C542* | Nonsense Mutation (SNP) | VAF 93/323 reads (29%) | catalogued as rs1396383344; called by muse, mutect2, varscan2
- RIF1 | c.3710C>T p.P1237L | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.194); catalogued as rs1418651120; called by muse, mutect2, varscan2
- RIMS1 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs777907746, COSV53477919, COSV99325333; called by muse, mutect2, varscan2
- RIMS1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53465098; called by muse, mutect2
- RIMS3 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 73/220 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.013); catalogued as COSV65504653; called by muse, mutect2, varscan2
- RIOX2 | c.590G>C p.R197P | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57725276; called by muse, mutect2, varscan2
- RIPOR2 | c.1009C>A p.Q337K | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52422256; called by muse, mutect2, varscan2
- RTN4RL1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58677550; called by muse, mutect2, varscan2
- RTP5 | c.1428C>A p.F476L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as rs375279566, COSV58320017; called by muse, mutect2, varscan2
- RYR2 | c.4432G>T p.E1478* | Nonsense Mutation (SNP) | VAF 44/185 reads (24%) | catalogued as COSV63723144; called by muse, mutect2, varscan2
- RYR3 | c.5008C>A p.P1670T | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as COSV66780775, COSV66794072; called by muse, mutect2, varscan2
- SACS | c.10784T>G p.L3595R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV66533520; called by muse, mutect2, varscan2
- SACS | c.9515A>G p.K3172R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV66544556; called by muse, mutect2, varscan2
- SAGE1 | c.2590G>T p.E864* | Nonsense Mutation (SNP) | VAF 87/94 reads (93%) | catalogued as COSV61014889; called by muse, varscan2
- SALL4 | c.2983dup p.V995Gfs*16 | Frame Shift Ins (INS) | VAF 10/64 reads (16%) | catalogued as rs753320334; called by mutect2, varscan2
- SALL4 | c.2284G>T p.D762Y | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53855863; called by muse, varscan2
- SAMD9L | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 140/364 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV100560834; called by muse, mutect2, varscan2
- SATB2 | c.2073C>A p.D691E | Missense Mutation (SNP) | VAF 149/319 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53478258; called by muse, mutect2, varscan2
- SBNO1 | c.4006C>T p.R1336W (on ENST00000420886; = p.R1335W on NM_018183.5) | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV57339340; called by muse, mutect2, varscan2
- SCAF8 | c.2867C>T p.S956L | Missense Mutation (SNP) | VAF 161/582 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.137); catalogued as rs753495761, COSV65789710; called by muse, mutect2, varscan2
- SCAMP4 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 53/62 reads (85%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV100280321; called by muse, mutect2, varscan2
- SCN10A | c.5257C>A p.P1753T | Missense Mutation (SNP) | VAF 107/343 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71861036; called by muse, mutect2, varscan2
- SCN7A | c.628A>C p.T210P | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV101313404; called by muse, mutect2
- SEC14L4 | c.75C>G p.D25E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1377792567; called by muse, mutect2, varscan2
- SEMA5A | c.2708C>A p.S903* | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as COSV66790213; called by muse, mutect2, varscan2
- SEPTIN4 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.617); catalogued as rs267604971; called by muse, mutect2, varscan2
- SERPINB12 | c.645G>T p.A215= | Splice Region (SNP) | VAF 65/232 reads (28%) | catalogued as rs1014451613, COSV54034944; called by muse, mutect2, varscan2
- SERPIND1 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV53139081; called by muse, mutect2, varscan2
- SF3B2 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV59429359; called by muse, mutect2, varscan2
- SH3GL2 | c.688G>T p.V230F | Missense Mutation (SNP) | VAF 159/583 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.254); catalogued as rs752535226; called by muse, mutect2, varscan2
- SH3PXD2B | c.1689G>A p.M563I | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs769620312; called by muse, mutect2, varscan2
- SH3TC2 | c.1585C>A p.R529S | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM127950, COSV60468071; called by muse, mutect2, varscan2
- SHTN1 | c.859-1G>T p.X287_splice | Splice Site (SNP) | VAF 52/59 reads (88%) | catalogued as COSV99599523; called by muse, mutect2, varscan2
- SIPA1L1 | c.3517G>T p.E1173* | Nonsense Mutation (SNP) | VAF 65/247 reads (26%) | catalogued as COSV62170040, COSV62170950; called by muse, mutect2, varscan2
- SIRPA | c.663C>A p.D221E | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV61536095; called by muse, mutect2, varscan2
- SLC16A10 | c.1436A>T p.E479V | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV100920838; called by muse, mutect2, varscan2
- SLC1A7 | c.254C>A p.S85Y | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV101019513; called by muse, mutect2
- SLC35G5 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 80/94 reads (85%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs758879812; called by muse, varscan2
- SLC5A11 | c.1887G>C p.E629D | Missense Mutation (SNP) | VAF 89/238 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV61743820; called by muse, mutect2, varscan2
- SLC8A1 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 80/152 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.272); catalogued as COSV60477579; called by muse, varscan2
- SLC9A4 | c.274A>T p.R92W | Missense Mutation (SNP) | VAF 129/213 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs971548372; called by muse, mutect2, varscan2
- SLITRK1 | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as COSV65678169; called by muse, mutect2
- SLITRK2 | c.1693G>T p.A565S | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1283547485, COSV59427817; called by muse, mutect2, varscan2
- SLITRK5 | c.1403G>T p.R468M | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV61524518; called by muse, mutect2, varscan2
- SMR3B | c.117A>C p.Q39H | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV100513391; called by muse, mutect2, varscan2
- SMYD1 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV70225313; called by muse, mutect2, varscan2
- SNAPC1 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 78/315 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs764113543; called by muse, mutect2, varscan2
- SNX19 | c.2479C>G p.L827V | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.134); catalogued as COSV56284406; called by muse, mutect2, varscan2
- SNX29 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs751174952; called by muse, mutect2, varscan2
- SNX31 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs769414323, COSV61265885; called by muse, mutect2, varscan2
- SOBP | c.1695C>A p.N565K | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); catalogued as rs1437904909; called by muse, mutect2, varscan2
- SORCS1 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as rs367597399; called by muse, varscan2
- SORCS3 | c.1055C>A p.A352E | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV63804214; called by muse, mutect2, varscan2
- SP140 | c.353T>A p.I118N | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV59447263; called by muse, mutect2, varscan2
- SP140 | c.1192G>T p.G398* | Nonsense Mutation (SNP) | VAF 57/429 reads (13%) | catalogued as COSV59450118; called by muse, mutect2, varscan2
- SPATA31D1 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 207/238 reads (87%) | catalogued as COSV61194900; called by muse, varscan2
- SPECC1 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 109/221 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.406); catalogued as rs983453230, COSV54961445; called by muse, mutect2, varscan2
- SPHKAP | c.3626G>T p.S1209I | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.36); catalogued as COSV60871932; called by muse, mutect2, varscan2
- SPNS1 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1196843508, COSV57955499; called by muse, mutect2, varscan2
- SPOCK2 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV100436478; called by muse, mutect2, varscan2
- SPP2 | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV51444512; called by muse, mutect2
- SPTA1 | c.2413G>T p.E805* | Nonsense Mutation (SNP) | VAF 69/131 reads (53%) | catalogued as COSV63757823; called by muse, mutect2, varscan2
- SRRT | c.1850G>C p.R617P | Missense Mutation (SNP) | VAF 143/433 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53818846; called by muse, mutect2, varscan2
- SSX5 | c.508G>T p.E170* (on ENST00000347757 / NM_175723.1; = p.E211* on NM_021015.4) | Nonsense Mutation (SNP) | VAF 183/426 reads (43%) | catalogued as COSV61256195; called by muse, mutect2, varscan2
- STRN | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.513); catalogued as rs754893597; called by muse, mutect2, varscan2
- SUN3 | c.184G>C p.G62R | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1182880214; called by muse, mutect2
- SUPT5H | c.1897G>T p.G633W | Missense Mutation (SNP) | VAF 84/98 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100782166; called by muse, mutect2, varscan2
- SYNE1 | c.3221G>T p.C1074F (on ENST00000367255 / NM_182961.4; = p.C1081F on NM_033071.3) | Missense Mutation (SNP) | VAF 130/470 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV99555928; called by muse, mutect2, varscan2
- SYNE2 | c.4606C>A p.L1536I | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59954621; called by muse, mutect2
- TAF3 | c.1396A>G p.M466V | Missense Mutation (SNP) | VAF 217/479 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs1221989632; called by muse, mutect2, varscan2
- TAF7 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs762912346; called by muse, varscan2
- TAS2R60 | c.876C>A p.H292Q | Missense Mutation (SNP) | VAF 279/678 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100223526; called by muse, mutect2, varscan2
- TCF21 | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 126/246 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52817965; called by muse, mutect2, varscan2
- TDRD3 | c.1462A>T p.N488Y | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV52165590; called by muse, mutect2, varscan2
- TENM2 | c.7045G>T p.D2349Y (on ENST00000518659 / NM_001122679.2; = p.D2110Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69139047; called by muse, mutect2, varscan2
- TESPA1 | c.426del p.T143Pfs*59 (on ENST00000316577 / NM_001098815.3; = p.T5Pfs*59 on NM_014796.2 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 68/155 reads (44%) | catalogued as rs1365960762; called by pindel, varscan2
- TET1 | c.96G>C p.K32N | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV101018451; called by muse, mutect2, varscan2
- TGIF2LX | c.488del p.P163Qfs*24 | Frame Shift Del (DEL) | VAF 48/78 reads (62%) | catalogued as COSV52214611; called by pindel, varscan2
- TGIF2LX | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 54/60 reads (90%) | catalogued as COSV52214013; called by muse, varscan2
- TIAM1 | c.1412-1G>T p.X471_splice | Splice Site (SNP) | VAF 37/92 reads (40%) | catalogued as COSV54540452; called by muse, varscan2
- TIMM29 | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53404697; called by muse, varscan2
- TINAGL1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs1489438150; called by muse, mutect2, varscan2
- TMEM177 | c.71G>A p.C24Y | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs747229852; called by muse, varscan2
- TMEM185A | c.336G>T p.W112C | Missense Mutation (SNP) | VAF 92/107 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57559340; called by muse, mutect2, varscan2
- TMPRSS12 | c.551A>T p.N184I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101269107; called by muse, mutect2, varscan2
- TMTC4 | c.-54-2A>G | Splice Site (SNP) | VAF 32/138 reads (23%) | catalogued as rs761777350; called by muse, mutect2, varscan2
- TNFRSF8 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.168); catalogued as COSV55799449; called by muse, mutect2, varscan2
- TNFRSF9 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.043); catalogued as COSV66349773; called by muse, mutect2, varscan2
- TNFSF4 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV99029633; called by muse, mutect2, varscan2
- TNR | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as rs1193211037; called by muse, mutect2, varscan2
- TPTE2 | c.1563G>T p.E521D (on ENST00000400230 / NM_199254.2; = p.E444D on NM_130785.3) | Missense Mutation (SNP) | VAF 75/81 reads (93%) | SIFT tolerated (0.33); PolyPhen benign (0.43); catalogued as COSV55019403; called by muse, mutect2, varscan2
- TRAK1 | c.1372G>A p.V458I (on ENST00000327628 / NM_001349247.2; = p.V400I on NM_014965.5) | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs368474947; called by muse, mutect2, varscan2
- TRGV3 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 112/477 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1279290972; called by muse, mutect2, varscan2
- TRIM29 | c.1697C>A p.T566N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.674); catalogued as COSV59279567; called by muse, mutect2, varscan2
- TRIM50 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV60792607; called by muse, mutect2, varscan2
- TRIM58 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV63572333; called by muse, mutect2, varscan2
- TRIML1 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV60194384; called by muse, mutect2, varscan2
- TRIOBP | c.6227G>T p.R2076L (on ENST00000644935 / NM_001039141.3; = p.R363L on NM_007032.5) | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs572469366; called by muse, varscan2
- TRPC6 | c.874G>T p.D292Y | Missense Mutation (SNP) | VAF 195/376 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100723747; called by muse, varscan2
- TRPM2 | c.166-1G>T p.X56_splice | Splice Site (SNP) | VAF 21/62 reads (34%) | catalogued as rs746035733; called by muse, mutect2, varscan2
- TRPV1 | c.2510G>T p.G837V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as COSV99440110; called by muse, mutect2, varscan2
- TSHR | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs1462898896, COSV99993063; called by muse, mutect2, varscan2
- TTC13 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as COSV64168104; called by muse, mutect2, varscan2
- TTI1 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1010608033; called by muse, mutect2, varscan2
- TTLL6 | c.1999G>C p.A667P (on ENST00000393382 / NM_001130918.3; = p.A360P on NM_173623.3) | Missense Mutation (SNP) | VAF 85/145 reads (59%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.132); catalogued as rs960233922; called by muse, mutect2, varscan2
- TTN | c.62879C>G p.S20960* (on ENST00000591111; = p.S13536* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 51/258 reads (20%) | catalogued as rs1223105615, COSV60208249; called by muse, mutect2, varscan2
- TTN | c.50005G>A p.E16669K (on ENST00000591111; = p.E9245K on NM_003319.4) | Missense Mutation (SNP) | VAF 13/137 reads (9%) | PolyPhen possibly damaging (0.73); catalogued as COSV60252745; called by muse, mutect2, varscan2
- TTN | c.6073G>A p.E2025K (on ENST00000591111; = p.E1979K on NM_003319.4) | Missense Mutation (SNP) | VAF 25/370 reads (7%) | PolyPhen benign (0.254); catalogued as COSV59861019, COSV59883795; called by muse, mutect2
- TTYH1 | c.800C>A p.T267K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV56612869; called by muse, mutect2, varscan2
- TUBB2B | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.018); catalogued as COSV52534052; called by muse, mutect2, varscan2
- TXNDC11 | c.2055G>C p.Q685H (on ENST00000356957 / NM_001303447.2; = p.Q658H on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/70 reads (84%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV51600850; called by muse, mutect2, varscan2
- UGT1A1 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV100530344, COSV59395637; called by muse, mutect2
- UNC5D | c.728T>C p.L243P | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.376); catalogued as COSV54802748; called by muse, mutect2, varscan2
- WASF3 | c.1024G>T p.G342* | Nonsense Mutation (SNP) | VAF 109/244 reads (45%) | catalogued as COSV58965274; called by muse, varscan2
- WDR17 | c.2499G>T p.Q833H | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1485726755; called by muse, mutect2, varscan2
- WDR49 | c.1315G>T p.D439Y (on ENST00000308378 / NM_001366158.1; = p.D780Y on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57705122; called by muse, mutect2, varscan2
- WNK1 | c.1063A>G p.I355V | Missense Mutation (SNP) | VAF 118/493 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs753222480; called by muse, mutect2, varscan2
- WNK4 | c.1244C>A p.T415K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.29); catalogued as COSV55907242; called by muse, mutect2, varscan2
- WNT10A | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as COSV51463005; called by muse, mutect2, varscan2
- WNT5B | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.36); catalogued as COSV60197867; called by muse, mutect2, varscan2
- WNT9B | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 220/328 reads (67%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs745497462; called by muse, mutect2, varscan2
- ZC3H10 | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.382); catalogued as COSV57769049; called by muse, mutect2, varscan2
- ZDHHC22 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1007920166; called by muse, mutect2, varscan2
- ZEB1 | c.2672C>T p.P891L | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.375); catalogued as rs369330183; called by muse, mutect2, varscan2
- ZFHX4 | c.2807G>A p.R936K | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.979); catalogued as rs749560165; called by muse, mutect2, varscan2
- ZFP90 | c.1157G>T p.R386M | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1424418518; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2492A>T p.Y831F | Missense Mutation (SNP) | VAF 183/204 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV100048143; called by muse, mutect2, varscan2
- ZMAT4 | c.564G>T p.M188I | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1379370094, COSV52704226; called by muse, mutect2, varscan2
- ZNF208 | c.2599G>T p.G867C | Missense Mutation (SNP) | VAF 111/185 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68112726; called by muse, mutect2, varscan2
- ZNF41 | c.2259G>T p.Q753H | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV57445000; called by muse, mutect2, varscan2
- ZNF521 | c.391A>G p.S131G | Missense Mutation (SNP) | VAF 120/589 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as rs377663212; called by muse, mutect2, varscan2
- ZNF536 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 135/362 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.442); catalogued as rs1425328578, COSV62828025; called by muse, mutect2, varscan2
- ZNF621 | c.513G>T p.M171I | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV59459399; called by muse, mutect2, varscan2
- ZNF628 | c.1514C>T p.T505M | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs780886909, COSV52700754; called by muse, mutect2, varscan2
- ZNF667 | c.963A>T p.Q321H | Missense Mutation (SNP) | VAF 124/132 reads (94%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV99410880; called by muse, mutect2, varscan2
- ZNF683 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV62876175; called by muse, mutect2, varscan2
- ZNF804A | c.3554C>A p.P1185Q | Missense Mutation (SNP) | VAF 157/476 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100167317, COSV56468377; called by mutect2, varscan2
- ZNF831 | c.1063C>G p.Q355E | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100925803; called by muse, mutect2, varscan2
- ZNF98 | c.383G>T p.S128I | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.729); catalogued as COSV100757581; called by muse, mutect2, varscan2
- ZPLD1 | c.1096C>T p.Q366* (on ENST00000466937 / NM_001329788.1; = p.Q382* on NM_175056.2) | Nonsense Mutation (SNP) | VAF 246/758 reads (32%) | catalogued as rs867145976; called by muse, mutect2, varscan2
- A2ML1 | c.2156C>A p.T719N | Missense Mutation (SNP) | VAF 222/841 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AARS2 | c.2296A>T p.I766F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2
- ABCA1 | c.1526A>T p.K509M | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA13 | c.2710G>T p.E904* | Nonsense Mutation (SNP) | VAF 91/179 reads (51%) | called by muse, mutect2, varscan2
- ABCA5 | c.4482G>T p.E1494D | Missense Mutation (SNP) | VAF 65/93 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- ABCA6 | c.2872A>T p.K958* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- ABCA8 | c.3199C>A p.P1067T | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ABCB10 | c.1153A>G p.M385V | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB6 | c.1906C>G p.L636V | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ABCC11 | c.3322G>T p.V1108L | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ABCC4 | c.1570G>T p.D524Y | Missense Mutation (SNP) | VAF 73/476 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ACAN | c.5447T>A p.V1816D | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); called by muse, varscan2
- ACBD4 | c.497G>T p.S166I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ACKR1 | c.731A>T p.N244I | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- ACKR3 | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 56/263 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSF3 | c.1597C>T p.L533F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ACSM5 | c.129C>A p.S43R | Missense Mutation (SNP) | VAF 65/70 reads (93%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACSS2 | c.1763T>C p.L588P | Missense Mutation (SNP) | VAF 44/506 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACTA1 | c.833A>G p.E278G | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACTC1 | c.1103G>A p.G368D | Missense Mutation (SNP) | VAF 116/129 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACTN2 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2
- ACTN3 | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.681); called by muse, varscan2
- ACVR1C | c.520G>C p.V174L | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACY3 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ADAM30 | c.1763dup p.T589Hfs*14 | Frame Shift Ins (INS) | VAF 67/247 reads (27%) | called by mutect2, pindel, varscan2
- ADAM30 | c.1395C>G p.D465E | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS15 | c.2008G>T p.D670Y | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ADAMTS16 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 160/344 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ADAMTS17 | c.2682C>G p.N894K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS18 | c.2119T>A p.C707S | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS19 | c.2902A>C p.T968P | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ADAMTS5 | c.2228A>T p.K743M | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ADAMTS9 | c.448T>A p.C150S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1772A>G p.N591S | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL3 | c.3737G>T p.G1246V | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ADCY10 | c.2129G>T p.C710F | Missense Mutation (SNP) | VAF 148/542 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ADCY2 | c.1808A>T p.Y603F | Missense Mutation (SNP) | VAF 102/202 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADCY7 | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.959A>C p.N320T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ADGRB1 | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- ADGRB3 | c.757+1G>C p.X253_splice | Splice Site (SNP) | VAF 38/63 reads (60%) | called by muse, mutect2, varscan2
- ADGRL3 | c.570A>T p.E190D (on ENST00000506720 / NM_001322402.2; = p.E122D on NM_015236.6) | Missense Mutation (SNP) | VAF 114/194 reads (59%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ADGRV1 | c.4467A>C p.K1489N | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ADGRV1 | c.9782G>A p.S3261N | Missense Mutation (SNP) | VAF 49/347 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ADH1C | c.1034C>A p.A345E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ADNP | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 21/335 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); called by muse, mutect2
- AGBL1 | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGBL1 | c.1199A>T p.Q400L | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- AGBL1 | c.2941A>G p.R981G | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- AGBL2 | c.2147+1G>T p.X716_splice | Splice Site (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- AGL | c.4408G>T p.G1470C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- AGMO | c.610-1G>T p.X204_splice | Splice Site (SNP) | VAF 29/171 reads (17%) | called by muse, mutect2, varscan2
- AHCTF1 | c.2762A>G p.N921S (on ENST00000366508; = p.N895S on NM_015446.5) | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AHNAK2 | c.7746G>T p.K2582N | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- AHR | c.1731A>T p.L577F | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- AHRR | c.1643G>C p.C548S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AKAP3 | c.2143T>G p.Y715D | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ALB | c.1139C>A p.T380N | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ALDH1A2 | c.475G>C p.G159R | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALMS1 | c.4519G>T p.G1507* | Nonsense Mutation (SNP) | VAF 49/133 reads (37%) | called by muse, mutect2, varscan2
- ALPP | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.298); called by muse, varscan2
- ANK2 | c.9227A>T p.Q3076L | Missense Mutation (SNP) | VAF 74/114 reads (65%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5240G>T p.G1747V | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKK1 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD17 | c.2645A>C p.Q882P | Missense Mutation (SNP) | VAF 104/130 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- ANKRD26 | c.4931G>T p.S1644I | Missense Mutation (SNP) | VAF 60/305 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- ANKRD45 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD7 | c.286T>A p.L96M | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKS1B | c.3173A>T p.Q1058L (on ENST00000547776 / NM_152788.4; = p.Q224L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/98 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ANKS6 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO2 | c.2465C>A p.S822Y (on ENST00000356134 / NM_001278597.3; = p.S826Y on NM_001278596.3) | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AOX1 | c.3961A>G p.K1321E | Missense Mutation (SNP) | VAF 29/290 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AP3D1 | c.2150-2A>T p.X717_splice | Splice Site (SNP) | VAF 14/22 reads (64%) | called by muse, varscan2
- AP4E1 | c.1251A>T p.L417F | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBB1 | c.123G>C p.Q41H | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOBR | c.2497G>T p.E833* (on ENST00000431282; = p.E842* on NM_018690.4) | Nonsense Mutation (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- APP | c.2218G>T p.A740S | Missense Mutation (SNP) | VAF 85/93 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APPBP2 | c.1394A>T p.Q465L | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AQP6 | c.118T>C p.F40L | Missense Mutation (SNP) | VAF 88/302 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ARAP1 | c.4160G>T p.W1387L (on ENST00000393609 / NM_001040118.2; = p.W1142L on NM_015242.4) | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARAP1 | c.1534G>C p.D512H (on ENST00000393609 / NM_001040118.2; = p.D267H on NM_015242.4) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2
- ARAP2 | c.2259+1G>T p.X753_splice | Splice Site (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- AREL1 | c.2241G>T p.E747D | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ARHGAP20 | c.1787T>G p.V596G | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARHGAP32 | c.3057G>T p.Q1019H (on ENST00000310343 / NM_001378025.1; = p.Q670H on NM_014715.4) | Missense Mutation (SNP) | VAF 230/360 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- ARHGAP32 | c.250A>T p.I84F | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ARHGAP32 | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP33 | c.1875A>C p.R625S | Missense Mutation (SNP) | VAF 82/430 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.116); called by muse, varscan2
- ARHGEF12 | c.507G>T p.M169I | Missense Mutation (SNP) | VAF 221/357 reads (62%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF25 | c.1490C>G p.P497R | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ARID4A | c.1531G>T p.E511* | Nonsense Mutation (SNP) | VAF 53/264 reads (20%) | called by muse, mutect2, varscan2
- ARIH2 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- ARMCX5 | c.1399A>G p.R467G | Missense Mutation (SNP) | VAF 86/100 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ARSF | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARSI | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASH1L | c.4438G>C p.E1480Q | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ASMT | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 67/332 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ASTN1 | c.3128G>T p.W1043L | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ASTN1 | c.1493G>A p.C498Y | Missense Mutation (SNP) | VAF 384/1527 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- ASTN1 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASTN2 | c.1781G>T p.W594L (on ENST00000313400 / NM_001365069.1; = p.W543L on NM_014010.5) | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ATG9A | c.2413C>G p.P805A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATP13A4 | c.2446A>T p.I816F | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- ATP2A3 | c.863G>T p.W288L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- ATP2B3 | c.2626G>T p.D876Y | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ATP6V0A4 | c.169A>T p.R57W | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP8A1 | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP8B4 | c.3277T>C p.Y1093H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- AWAT2 | c.131C>A p.P44Q | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- B3GALT2 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BAAT | c.697T>C p.S233P | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BABAM2 | c.926T>G p.L309R | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BACH2 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 58/180 reads (32%) | called by muse, mutect2, varscan2
- BAIAP3 | c.1857C>A p.F619L | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- BBS10 | c.845A>T p.Q282L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- BCAR1 | c.2338G>T p.A780S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- BCAR3 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- BCAS1 | c.1640A>G p.E547G | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCOR | c.305_306delinsCTT p.R102Pfs*2 | Frame Shift Ins (INS) | VAF 20/50 reads (40%) | called by pindel, varscan2*
- BDP1 | c.1966G>T p.E656* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- BEND5 | c.1193G>T p.C398F | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BGLAP | c.6A>T p.R2S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2
- BICD1 | c.699A>T p.E233D | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- BIRC5 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.066); called by muse, mutect2
- BIRC6 | c.8588T>C p.V2863A | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2
- BMPER | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BOLL | c.384G>T p.M128I | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BPIFB4 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- BPIFB4 | c.1490T>A p.L497Q | Missense Mutation (SNP) | VAF 127/248 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- BRICD5 | c.715C>G p.L239V (on ENST00000562360; = p.L207V on NM_182563.3) | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BRINP2 | c.2215G>C p.D739H | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BSND | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BTAF1 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- BTG4 | c.237T>A p.S79R | Missense Mutation (SNP) | VAF 148/245 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- C1QTNF9 | c.793T>A p.S265T | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C1orf52 | c.147G>T p.R49S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, varscan2
- C3orf56 | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- C4orf45 | c.445C>A p.Q149K | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C6orf58 | c.222T>G p.Y74* | Nonsense Mutation (SNP) | VAF 12/179 reads (7%) | called by muse, mutect2
- C8A | c.542A>T p.Y181F | Missense Mutation (SNP) | VAF 98/326 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CA10 | c.631A>G p.K211E | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- CACNA1C | c.3827A>C p.K1276T | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- CACNA1D | c.4250C>G p.P1417R (on ENST00000350061 / NM_001128840.3; = p.P1437R on NM_000720.4) | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2
- CACNA1G | c.6736T>A p.C2246S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.48); called by muse, mutect2
- CACNA1H | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, varscan2
- CACNA1S | c.418del p.E140Nfs*13 | Frame Shift Del (DEL) | VAF 69/326 reads (21%) | called by mutect2, pindel, varscan2
- CACNA2D1 | c.1741G>T p.G581W (on ENST00000356253 / NM_001366867.1; = p.G562W on NM_000722.4) | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CACNA2D3 | c.2863A>G p.M955V | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAD | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- CADM3 | c.196G>T p.A66S (on ENST00000368125 / NM_001127173.3; = p.A100S on NM_021189.5) | Missense Mutation (SNP) | VAF 93/163 reads (57%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- CALN1 | c.305G>T p.G102V (on ENST00000329008 / NM_001017440.3; = p.G144V on NM_031468.4) | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CAMK4 | c.85G>T p.V29F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); called by muse, varscan2
- CAMK4 | c.1229C>A p.A410D | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPRIN2 | c.3054A>T p.E1018D | Missense Mutation (SNP) | VAF 67/74 reads (91%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CARD14 | c.278del p.K93Sfs*32 | Frame Shift Del (DEL) | VAF 29/89 reads (33%) | called by mutect2, pindel, varscan2
- CARMIL3 | c.1555T>G p.F519V | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CASK | c.279-1G>T p.X93_splice | Splice Site (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- CASP7 | c.517A>C p.T173P | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- CASP8AP2 | c.4103C>T p.S1368F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CATIP | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CATSPER1 | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CATSPERB | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 228/448 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.42); called by muse, varscan2
- CATSPERG | c.2698C>A p.R900S | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CBLB | c.1448C>G p.S483C | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCDC105 | c.788C>A p.S263* | Nonsense Mutation (SNP) | VAF 70/74 reads (95%) | called by muse, mutect2, varscan2
1,718 further variants in this file (1,141 protein-altering or splice-affecting, 515 silent, 62 other) are not listed here.
